Somatic mutation profile of tumor specimen TCGA-CZ-5982-01A (aliquot TCGA-CZ-5982-01A-11D-1669-08) from TCGA case TCGA-CZ-5982, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.1 years (21,592 days).
Specimen TCGA-CZ-5982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b150a732-02c2-4b63-b649-556d851fdb75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5982-11A (Solid Tissue Normal), aliquot TCGA-CZ-5982-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a284f261-203e-4ef9-9522-e44c3dcad723

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 27, Silent 11, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSK | c.437C>A p.T146K | Missense Mutation (SNP) | VAF 89/283 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV66169923; called by muse, mutect2, varscan2
- BRCA2 | c.8521T>A p.F2841I | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66456494; called by muse, mutect2, varscan2
- CCDC190 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 79/386 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.334); catalogued as COSV100905797, COSV63363126, COSV63363346; called by muse, mutect2, varscan2
- CDK13 | c.1126T>C p.Y376H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV51702427; called by muse, mutect2
- CXorf38 | c.291T>A p.D97E | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.059); catalogued as COSV59947818; called by muse, mutect2, varscan2
- DLG1 | c.1386G>C p.R462S | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.47); catalogued as COSV58385645; called by muse, mutect2, varscan2
- EEF1G | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as rs1565262742, COSV57747032; called by muse, mutect2
- FAM71E1 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV58542552; called by muse, mutect2, varscan2
- FBL | c.297T>A p.C99* | Nonsense Mutation (SNP) | VAF 39/92 reads (42%) | catalogued as COSV55683130; called by muse, mutect2, varscan2
- HMBOX1 | c.1043T>A p.L348Q | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV55069646; called by muse, mutect2, varscan2
- HSPG2 | c.6799G>A p.V2267M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.354); catalogued as rs759420792, COSV65973374; called by muse, mutect2, varscan2
- IRX5 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58059296, COSV58059422; called by muse, mutect2, varscan2
- ITGAX | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs779296419, COSV51641307; called by muse, mutect2, varscan2
- MPP6 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0.088); catalogued as COSV56039888; called by muse, mutect2, varscan2
- NDUFS3 | c.184G>T p.G62* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as COSV55455335, COSV55455779; called by muse, mutect2, varscan2
- PBRM1 | c.3783C>A p.Y1261* (on ENST00000296302 / NM_001366071.2; = p.Y1236* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 46/99 reads (46%) | catalogued as COSV56284634; called by muse, mutect2, varscan2
- PGAP4 | c.1163T>G p.I388S | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV66387910, COSV66388049; called by muse, mutect2, varscan2
- PNPLA3 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53379086; called by muse, mutect2, varscan2
- PRKG1 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.208); catalogued as COSV100907509, COSV64773027; called by muse, mutect2, varscan2
- RIMKLB | c.545A>G p.H182R | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.143); catalogued as rs1250690951, COSV55238160; called by muse, mutect2, varscan2
- RNF115 | c.596C>G p.T199R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV65165022; called by muse, mutect2, varscan2
- SALL3 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV73306179; called by mutect2, varscan2
- SMG7 | c.2459A>T p.Y820F | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61629819, COSV61632379; called by muse, mutect2, varscan2
- SPIDR | c.1088T>A p.F363Y | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52380939; called by muse, mutect2, varscan2
- TOPBP1 | c.3106G>A p.V1036I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53437677; called by muse, mutect2, varscan2
- UGT1A4 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV59392054; called by muse, mutect2, varscan2
- UPRT | c.524T>A p.F175Y | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as COSV64912450; called by muse, mutect2, varscan2
- VHL | c.493del p.V165Lfs*5 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as CM031757, CM074631, COSV56566513; called by mutect2, pindel, varscan2
- WDR93 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV51533383; called by muse, mutect2, varscan2
- ZNF181 | c.1481G>A p.C494Y | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67626911; called by muse, mutect2, varscan2
- ZNF395 | c.1492T>C p.W498R | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60429300; called by muse, mutect2, varscan2
- EXOSC10 | c.991del p.I331Ffs*42 | Frame Shift Del (DEL) | VAF 72/350 reads (21%) | called by mutect2, pindel, varscan2
- FBXL13 | c.408del p.P137Lfs*11 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- SIRT1 | c.1728del p.E577Kfs*24 | Frame Shift Del (DEL) | VAF 25/124 reads (20%) | called by mutect2, pindel, varscan2
- SLC15A1 | c.1067+2_1067+10del p.X356_splice | Splice Site (DEL) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- ADGRA2 | c.2292C>T p.G764= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs147055217; called by muse, mutect2, varscan2
- APPL1 | c.1038T>A p.S346= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as COSV55701676; called by muse, mutect2, varscan2
- DOT1L | c.687G>A p.R229= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as rs1316911157, COSV67110806; called by muse, mutect2
- FBLN1 | c.792C>T p.D264= | Silent (SNP) | VAF 43/165 reads (26%) | catalogued as rs144704783; called by muse, mutect2, varscan2
- HMSD | c.366C>T p.F122= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs772541743, COSV68816777; called by muse, mutect2, varscan2
- IRF2BPL | c.2091G>C p.V697= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV53147834; called by muse, varscan2
- RNF213 | c.10735T>C p.L3579= | Silent (SNP) | VAF 39/133 reads (29%) | catalogued as COSV60401275; called by muse, mutect2, varscan2
- SALL4 | c.1107G>T p.V369= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as rs961240844, COSV53853607; called by muse, mutect2, varscan2
- SON | c.1200T>A p.T400= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV51662547; called by muse, mutect2, varscan2
- SORCS3 | c.3300G>T p.G1100= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs748344619, COSV63802765, COSV63814647; called by muse, mutect2, varscan2
- UBR2 | c.1717C>T p.L573= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV65750752; called by muse, mutect2, varscan2
